TCGA case TCGA-02-2486 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/79a68b32-29a3-47bf-9b2b-643ec7323d73

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 618 days (1.7 years).

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 64.0 years (23,394 days); Year of diagnosis: 2008; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 66 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 24 days; Days to treatment end: 66 days; Prescribed dose: 75; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 67 days; Days to treatment end: 440 days (1.2 years); Number of cycles: 12; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Isotretinoin; Initial disease status: Progressive Disease; Days to treatment start: 130 days; Days to treatment end: 230 days; Number of cycles: 4; Prescribed dose: 40; Prescribed dose units: mg; Route of administration: Oral.

Follow-up (3 entries)
- Days to follow up: 493 days (1.3 years); Disease response: With Tumor.
- Days to follow up: 618 days (1.7 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-2486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.1.
  Slide TCGA-02-2486-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-02-2486-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-02-2486-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Accutane; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Temodar.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 618 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 618 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 618 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-02-2486-01A-01D-0784-01): tumor purity 0.72, ploidy 1.9, whole-genome doublings 0.
